Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JG, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JG-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site D⁴ Kidney NOS C64.9
QW 4/28/14

Final Diagnosis

- A. LEFT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type 2, Fuhrman nuclear grade 3 of 4.
See Key Pathological Findings.
- B. DEEP MARGIN, PARTIAL NEPHRECTOMY:
Renal parenchyma, negative for carcinoma.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Key Pathological Findings

Tumor type:	Renal cell carcinoma, papillary type 2.
Nuclear grade:	Fuhrman nuclear grade 3 of 4.
Pattern of growth:	Papillary.
Tumor size:	2.8 cm.
Invasion through Renal capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein invasion:	Not applicable.
Surgical margins:	Free.
Non-neoplastic kidney:	Focal mild chronic inflammation.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stage:	pT1aNXMX.

Specimen(s) Received

- A LEFT PARTIAL NEPHRECTOMY FS
B DEEP MARGIN LEFT PARTIAL NEPHRECTOMY FS

Clinical History

Left renal mass.

Preoperative Diagnosis

Left renal mass.

Intraoperative Consultation

FSA1: LEFT PARTIAL NEPHRECTOMY:
Papillary carcinoma. Parenchymal margin negative.

FSB1: DEEP MARGIN LEFT PARTIAL NEPHRECTOMY:
Benign renal tissue. No evidence of malignancy.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

[page 2 of 2]
I, _____, have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. Specimen A is received fresh for frozen section, labeled "left partial nephrectomy, ink is margin" and consists of a partial nephrectomy (3 x 3 x 1 cm) with a moderate amount of perinephric adipose tissue attached. The specimen measures in overall dimension, 4.5 x 5 x 2 cm. The specimen is oriented according to the surgeon's designation and is inked as follows: Parenchymal resection margin is inked blue and perinephric adipose tissue resection margin is inked green. The specimen is serially sectioned to reveal an irregular to roughly ovoid, partially solid and partially cystic tumor which measures 2.8 x 2.5 x 0.8 cm. The tumor is bulging capsule and extends to within 0.1 cm of the closest parenchymal margin. Representative section of the specimen with tumor in relation to the closest margin is submitted for frozen section as FSA1. Representative section of the specimen is submitted to the Tissue Procurement Laboratory. The remainder of the partial nephrectomy is submitted entirely in 7 cassettes A2-A8.

B. Specimen B is received fresh for frozen section, labeled "deep margin left partial nephrectomy, ink is margin" and consists of an irregular fragment of tan-red-brown, rubbery tissue measuring 1.5 x 0.2 x 0.2 cm. The specimen is oriented according to the surgeon's designation and the true margin is re-inked blue. No tissue is submitted to the Tissue Procurement Laboratory. The specimen is submitted entirely for frozen section as FSB1.

Source: NCI Genomic Data Commons file 37b5da06-fd66-4412-80a2-3638b24b2d27 (TCGA-2Z-A9JG.4AA9CDF4-596B-4F79-A94A-ED618A789120.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).